HCMI case HCM-BROD-0353-C64 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b1ed6908-e164-4e0f-accd-11605edf4c81

Demographics
Sex at birth: female; Year of birth: 2003; Vital status: Dead; Days to death: 101 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Medullary carcinoma, NOS: ICD-O-3 morphology code: 8510/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Classification of tumor: primary; Age at diagnosis: 14.0 years (5,113 days); Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Prior treatment: No; Residual disease: RX; Sites of involvement: Kidney, NOS.
   Pathology details: Additional pathology findings: Clostridioides difficile (c. diff); Lymph nodes positive: 0; Lymph nodes tested: 0; Lymphatic invasion present: No; Necrosis present: No; Rhabdoid present: No; Sarcomatoid present: No; Tumor largest dimension diameter: 9 cm; Vascular invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 28 days; Days to treatment end: 73 days.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Pembrolizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 73 days; Days to treatment end: 95 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Hormone Therapy, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 88.

Molecular and laboratory tests
- CD274 (IHC): Positive.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 61 kg.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample HCM-BROD-0353-C64-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Human Original Cells; Preservation method: Frozen.
- Sample HCM-BROD-0353-C64-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 13.
